Somatic mutation profile of tumor specimen TCGA-AA-3939-01A (aliquot TCGA-AA-3939-01A-01W-0995-10) from TCGA case TCGA-AA-3939, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 83.3 years (30,439 days).
Specimen TCGA-AA-3939-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b59c4010-c2c7-4379-b90d-71fca70e658a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3939-10A (Blood Derived Normal), aliquot TCGA-AA-3939-10A-01W-0995-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26c11152-4784-45a7-b0bb-dee4496be0d4

The open-access MAF lists 123 somatic variants for this specimen: 99 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 22, Nonsense Mutation 12, Frame Shift Del 2, 3'UTR 1, In Frame Del 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER1 | c.1057C>T p.R353* | Nonsense Mutation (SNP) | VAF 66/79 reads (84%) | catalogued as rs137852216, CM090021, COSV57654256, COSV57668550; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 19/48 reads (40%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CFP | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs132630259, CM950925, COSV55949739; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ITGA8 | c.1219G>A p.G407R | Missense Mutation (SNP) | VAF 125/176 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374664941, CM140876; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 20/42 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 41/78 reads (53%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACIN1 | c.2717G>A p.G906D | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.988); catalogued as COSV52983270; called by muse, mutect2, varscan2
- ACSL5 | c.326A>G p.K109R (on ENST00000354273; = p.K165R on NM_016234.3) | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV61134130; called by muse, mutect2, varscan2
- ADAMTS16 | c.3626A>G p.K1209R | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs755448042, COSV56993229, COSV56997939; called by muse, mutect2, varscan2
- ADCY8 | c.1897G>A p.V633M | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.921); catalogued as rs201550256; called by muse, mutect2, varscan2
- AFF4 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 94/671 reads (14%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.996); catalogued as rs765756314, COSV54800888; called by muse, mutect2, varscan2
- ALDH16A1 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140469932; called by muse, mutect2, varscan2
- APC | c.1624C>T p.Q542* | Nonsense Mutation (SNP) | VAF 108/507 reads (21%) | catalogued as CM071554, COSV57324072; called by muse, mutect2, varscan2
- BOC | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs745518240, COSV56355502; called by muse, mutect2, varscan2
- CD36 | c.404T>C p.F135S | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.403); catalogued as COSV59221175; called by muse, mutect2, varscan2
- CNBD1 | c.806T>G p.V269G | Missense Mutation (SNP) | VAF 53/326 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.282); catalogued as COSV73072512; called by muse, mutect2, varscan2
- COL12A1 | c.3902G>T p.R1301L | Missense Mutation (SNP) | VAF 73/165 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.958); catalogued as COSV59390351; called by muse, mutect2, varscan2
- COL24A1 | c.5105G>A p.R1702Q | Missense Mutation (SNP) | VAF 129/604 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs766007512, COSV65306703; called by muse, mutect2, varscan2
- CRISPLD1 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs541154941, COSV51544170; called by muse, mutect2, varscan2
- CTDSP1 | c.137T>G p.V46G | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as COSV51920317; called by muse, mutect2, varscan2
- DIP2A | c.4660C>T p.R1554W | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1345714953, COSV59476868; called by muse, mutect2, varscan2
- DNAH10 | c.1505G>A p.R502Q (on ENST00000409039; = p.R441Q on NM_207437.3) | Missense Mutation (SNP) | VAF 131/287 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV69004718; called by muse, mutect2, varscan2
- DYDC2 | c.296C>T p.T99M | Missense Mutation (SNP) | VAF 110/253 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); catalogued as rs142842576; called by muse, mutect2, varscan2
- EGF | c.1762C>T p.R588C | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as rs758800260, COSV54486085; called by muse, mutect2, varscan2
- EXOSC5 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 74/518 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs772859389, COSV54200275; called by muse, mutect2, varscan2
- FAM71C | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 73/330 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as rs372415607; called by muse, mutect2, varscan2
- FBXO39 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 100/266 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761295686; called by muse, mutect2, varscan2
- FEZF2 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 101/466 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51863895; called by muse, mutect2, varscan2
- FLT3 | c.1913C>G p.S638* | Nonsense Mutation (SNP) | VAF 33/592 reads (6%) | catalogued as COSV54043277; called by muse, mutect2
- GPR101 | c.505G>A p.G169S | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53240756; called by muse, mutect2, varscan2
- GPRIN3 | c.1221A>C p.E407D | Missense Mutation (SNP) | VAF 93/526 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.023); catalogued as COSV60886764; called by muse, mutect2, varscan2
- HPS1 | c.1900G>A p.D634N | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV100282858; called by muse, mutect2, varscan2
- HS6ST2 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.959); catalogued as COSV63715009; called by muse, mutect2, varscan2
- IGHG2 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs745454231; called by muse, mutect2, varscan2
- IGHV2-5 | c.155G>C p.G52A | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.595); catalogued as rs371144937; called by muse, mutect2, varscan2
- KCTD8 | c.1273C>G p.L425V | Missense Mutation (SNP) | VAF 117/718 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.057); catalogued as COSV63598956; called by muse, mutect2, varscan2
- KRT40 | c.1259C>T p.A420V | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.1); catalogued as rs1161128429; called by muse, mutect2
- L3MBTL3 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 415/944 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs915274432; called by muse, mutect2, varscan2
- LCE2C | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 93/112 reads (83%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.895); catalogued as rs777666120, COSV64228433; called by muse, mutect2, varscan2
- LILRB5 | c.745G>A p.G249S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.306); catalogued as rs1308400353; called by muse, varscan2
- LRRC32 | c.1705C>G p.Q569E | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.348); catalogued as rs753297630, COSV52635170, COSV52636360; called by muse, mutect2, varscan2
- MMP2 | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 199/465 reads (43%) | catalogued as COSV54601859, COSV99029420, COSV99527668; called by muse, mutect2, varscan2
- MUC16 | c.43187C>T p.S14396L | Missense Mutation (SNP) | VAF 129/217 reads (59%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.966); catalogued as rs760092374; called by muse, mutect2, varscan2
- MYO1H | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 44/398 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.355); catalogued as rs1272052176; called by muse, mutect2, varscan2
- NRG1 | c.148G>A p.G50R (on ENST00000523534; = p.G197R on NM_013962.2) | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs1048175640; called by muse, mutect2, varscan2
- OAS2 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 43/404 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs533259756, COSV60801459, COSV60802672; called by muse, mutect2, varscan2
- OGFOD3 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762940701; called by muse, mutect2, varscan2
- OR51B2 | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs747897739, COSV60918126; called by muse, mutect2, varscan2
- OR5K3 | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 351/789 reads (44%) | catalogued as COSV67350846; called by muse, mutect2, varscan2
- PCDH15 | c.2057T>A p.L686Q | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57290982, COSV57307750; called by muse, mutect2, varscan2
- PCDH9 | c.2147C>T p.T716I | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV60566356; called by muse, mutect2, varscan2
- PDCD6 | c.367G>A p.G123S | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373052818, COSV53776846; called by muse, mutect2, varscan2
- PLK1 | c.1090C>T p.R364* | Nonsense Mutation (SNP) | VAF 44/146 reads (30%) | catalogued as COSV55621613; called by muse, mutect2, varscan2
- PRX | c.2819G>A p.G940E | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1322545345, COSV52534280; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRU | c.3982C>T p.R1328W | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752010143; called by muse, mutect2, varscan2
- RBAK | c.133G>C p.V45L | Missense Mutation (SNP) | VAF 316/1657 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV62332688; called by muse, mutect2, varscan2
- RGL1 | c.1352A>G p.E451G (on ENST00000360851 / NM_001297672.2; = p.E486G on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58982022, COSV58998465; called by muse, mutect2, varscan2
- SEMA5B | c.3253G>A p.G1085R | Missense Mutation (SNP) | VAF 78/369 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.354); catalogued as rs372894044; called by muse, mutect2, varscan2
- SERPINF1 | c.907C>T p.R303* | Nonsense Mutation (SNP) | VAF 86/197 reads (44%) | catalogued as rs763291398; called by muse, varscan2
- SFMBT2 | c.2098G>A p.V700M | Missense Mutation (SNP) | VAF 63/167 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs374674288; called by muse, mutect2, varscan2
- SNW1 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 54/295 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55054664; called by muse, mutect2, varscan2
- SPANXB1 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 42/686 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as rs1302097442, COSV71886004; called by muse, mutect2
- SPRR2F | c.200G>T p.C67F | Missense Mutation (SNP) | VAF 235/1949 reads (12%) | PolyPhen benign (0.077); catalogued as COSV64207160; called by muse, mutect2, varscan2
- SPTBN4 | c.7628C>T p.S2543L | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs760258956, COSV52544451; called by muse, mutect2, varscan2
- TGM2 | c.370G>T p.G124C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63932605; called by mutect2, varscan2
- TMEM273 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 411/711 reads (58%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV65152135; called by muse, mutect2, varscan2
- TNR | c.2788G>A p.E930K | Missense Mutation (SNP) | VAF 190/1197 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.332); catalogued as rs531733667, COSV54868765; called by muse, mutect2, varscan2
- VARS2 | c.863C>T p.S288L | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs374148426; called by muse, mutect2, varscan2
- VWC2L | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 186/241 reads (77%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.818); catalogued as rs754827622, COSV56970559; called by muse, mutect2, varscan2
- WBP4 | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 47/190 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.143); catalogued as rs760308349, COSV65273607; called by muse, mutect2, varscan2
- ZNF583 | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 28/161 reads (17%) | catalogued as rs780680078; called by muse, mutect2, varscan2
- ACSS2 | c.517C>A p.L173I | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- ACTL6A | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 66/1058 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2
- BPIFB4 | c.1477A>C p.K493Q | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.043); called by muse, mutect2
- COL9A1 | c.1822C>T p.Q608* | Nonsense Mutation (SNP) | VAF 62/236 reads (26%) | called by muse, mutect2, varscan2
- HECW2 | c.2962C>T p.P988S | Missense Mutation (SNP) | VAF 30/226 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IPO8 | c.289G>T p.V97L | Missense Mutation (SNP) | VAF 155/1535 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- ISL1 | c.757G>C p.D253H | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- LRP1B | c.12242T>G p.F4081C | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- LRP2 | c.5495C>A p.S1832* | Nonsense Mutation (SNP) | VAF 77/627 reads (12%) | called by muse, mutect2, varscan2
- MYLK3 | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- NDN | c.14G>T p.S5I | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- NLGN4X | c.752T>A p.F251Y | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR7A10 | c.300G>C p.Q100H | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OR9A4 | c.749T>C p.I250T | Missense Mutation (SNP) | VAF 16/504 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2
- OTOGL | c.5231T>G p.L1744* (on ENST00000547103; = p.L1735* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 40/264 reads (15%) | called by muse, mutect2, varscan2
- PCDHA12 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PON1 | c.489_491del p.L164del | In Frame Del (DEL) | VAF 192/631 reads (30%) | called by mutect2, varscan2
- PRPF19 | c.1318del p.S440Hfs*2 | Frame Shift Del (DEL) | VAF 24/78 reads (31%) | called by mutect2, varscan2
- PRPF8 | c.3488G>A p.R1163Q | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RAD54L2 | c.885_901del p.S296Yfs*37 | Frame Shift Del (DEL) | VAF 107/392 reads (27%) | called by mutect2, varscan2
- RNF216 | c.1706C>T p.P569L (on ENST00000425013 / NM_207116.3; = p.P626L on NM_207111.4) | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.241); called by muse, varscan2
- SH3GL2 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- SOX9 | c.867dup p.D290Rfs*6 | Frame Shift Ins (INS) | VAF 10/29 reads (34%) | called by mutect2, varscan2
- TRDN | c.560A>C p.K187T | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- WDSUB1 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0.013); called by muse, mutect2
- ZBBX | c.2018T>C p.I673T | Missense Mutation (SNP) | VAF 59/264 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- ZNF41 | c.1415G>A p.C472Y | Missense Mutation (SNP) | VAF 222/271 reads (82%) | SIFT deleterious (0.01); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ZNF813 | c.1521A>C p.K507N | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.75); PolyPhen benign (0.01); called by muse, mutect2
- ABCC6 | c.198C>T p.S66= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as COSV52748764; called by muse, mutect2, varscan2
- ADAMTS19 | c.3543G>A p.V1181= | Silent (SNP) | VAF 24/306 reads (8%) | catalogued as COSV50785677; called by muse, mutect2
- ADGRB2 | c.1731G>A p.A577= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as rs370752253; called by muse, varscan2
- ADSS1 | c.207C>T p.A69= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as rs761935811; called by muse, mutect2, varscan2
- CDH11 | c.843C>T p.A281= | Silent (SNP) | VAF 219/577 reads (38%) | catalogued as rs746814113, COSV51768799, COSV99217306; called by muse, mutect2, varscan2
- DENND2A | c.2988G>A p.L996= | Silent (SNP) | VAF 47/144 reads (33%) | catalogued as COSV52060952; called by muse, mutect2, varscan2
- DMBT1 | c.2964A>G p.E988= (on ENST00000338354 / NM_001377530.1; = p.E489= on NM_004406.3) | Silent (SNP) | VAF 206/555 reads (37%) | catalogued as COSV57567799; called by muse, mutect2, varscan2
- DNAH11 | c.5397C>T p.I1799= | Silent (SNP) | VAF 170/706 reads (24%) | catalogued as COSV60987592; called by muse, mutect2, varscan2
- EXOC3 | c.156G>A p.Q52= | Silent (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- FAM47A | c.2043G>A p.T681= | Silent (SNP) | VAF 109/496 reads (22%) | catalogued as rs749581923, COSV60500492; called by muse, mutect2, varscan2
- FAT3 | c.1443G>T p.V481= | Silent (SNP) | VAF 6/85 reads (7%) | called by muse, mutect2
- FRMD4A | c.1176G>A p.K392= | Silent (SNP) | VAF 46/222 reads (21%) | catalogued as COSV52738780; called by muse, mutect2, varscan2
- GRIN2A | c.1278C>T p.T426= | Silent (SNP) | VAF 85/372 reads (23%) | catalogued as rs776324005, COSV58029755; called by muse, mutect2, varscan2
- LRRC20 | c.87G>A p.L29= | Silent (SNP) | VAF 82/316 reads (26%) | catalogued as COSV62939553; called by muse, mutect2, varscan2
- MUSK | c.2526G>C p.L842= | Silent (SNP) | VAF 35/172 reads (20%) | catalogued as COSV51899247; called by muse, mutect2, varscan2
- NUDT19 | c.1086C>T p.H362= | Silent (SNP) | VAF 33/109 reads (30%) | catalogued as COSV67959391; called by muse, mutect2, varscan2
- NUMB | c.783C>T p.I261= (on ENST00000355058; = p.I250= on NM_003744.5) | Silent (SNP) | VAF 79/306 reads (26%) | catalogued as COSV61832674; called by muse, mutect2, varscan2
- RGMA | c.1158C>T p.G386= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as rs201262127; called by muse, mutect2, varscan2
- RUNX3 | c.9G>A p.S3= | Silent (SNP) | VAF 74/112 reads (66%) | catalogued as rs755295660, COSV58846542; called by muse, mutect2, varscan2
- TENM2 | c.3051C>T p.P1017= (on ENST00000518659 / NM_001122679.2; = p.P785= on NM_001080428.3) | Silent (SNP) | VAF 102/677 reads (15%) | catalogued as rs767158225, COSV69144485; called by muse, mutect2, varscan2
- TNFSF14 | c.72G>A p.L24= | Silent (SNP) | VAF 13/161 reads (8%) | called by muse, mutect2
- ZNF607 | c.99G>A p.E33= | Silent (SNP) | VAF 23/317 reads (7%) | called by muse, mutect2
- FABP5P3 | chr7:152445853 G>A | 3'Flank (SNP) | VAF 10/38 reads (26%) | catalogued as rs748950579; called by muse, varscan2
- FGFR3 | c.*251C>T | 3'UTR (SNP) | VAF 5/20 reads (25%) | catalogued as rs370064407; called by muse, mutect2, varscan2
